Somatic mutation profile of tumor specimen TCGA-78-8662-01A (aliquot TCGA-78-8662-01A-11D-2393-08) from TCGA case TCGA-78-8662, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 53.6 years (19,563 days).
Specimen TCGA-78-8662-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6685804f-face-4cd7-9d8d-7e430858ddc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-8662-10A (Blood Derived Normal), aliquot TCGA-78-8662-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b232dcc8-e157-4d9d-bf18-83d75b31a70b

The open-access MAF lists 1,251 somatic variants for this specimen: 941 protein-altering or splice-affecting, 279 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 818, Silent 279, Nonsense Mutation 61, Splice Site 21, Frame Shift Del 18, Intron 17, Splice Region 14, RNA 10, Translation Start Site 4, 3'UTR 3, Frame Shift Ins 3, Nonstop Mutation 1.

Variants (750 of 1,251; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>T p.G506V (on ENST00000288602 / NM_001374244.1; = p.G466V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 78/88 reads (89%) | hotspot (GDC flag); catalogued as rs730882001, COSV52677910, COSV52844585, COSV53637782; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TUBA1A | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.934); catalogued as rs1565626872, CM145638, COSV55498842; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.2650C>T p.H884Y | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101201280; called by muse, mutect2, varscan2
- ABCA9 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs780394943, COSV100383472; called by muse, mutect2, varscan2
- ABCB11 | c.2920G>T p.A974S | Missense Mutation (SNP) | VAF 74/168 reads (44%) | SIFT tolerated (0.84); PolyPhen benign (0.212); catalogued as COSV99793038; called by muse, mutect2, varscan2
- ABCC9 | c.2261A>T p.Y754F | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as COSV99687174; called by muse, mutect2, varscan2
- AC005833.1 | c.1210T>C p.C404R | Missense Mutation (SNP) | VAF 53/64 reads (83%) | SIFT deleterious, low confidence (0); catalogued as COSV99363234; called by muse, mutect2, varscan2
- AC090517.4 | c.175G>T p.G59* | Nonsense Mutation (SNP) | VAF 13/15 reads (87%) | catalogued as COSV99975107; called by muse, mutect2, varscan2
- ACAP3 | c.617G>A p.S206N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100686768; called by muse, mutect2, varscan2
- ACAT1 | c.106A>C p.K36Q | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99759412; called by muse, mutect2, varscan2
- ACSM5 | c.1523C>A p.P508H | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100089520; called by muse, mutect2, varscan2
- ACSS3 | c.1421A>C p.Q474P | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV99699438; called by muse, mutect2, varscan2
- ACTC1 | c.67T>A p.F23I | Missense Mutation (SNP) | VAF 88/106 reads (83%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.609); catalogued as CM1414557, COSV99292123; called by muse, varscan2
- ACTL6B | c.953C>T p.T318I | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV99355754; called by muse, mutect2, varscan2
- ACTR3B | c.683A>T p.K228M | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99754513; called by muse, mutect2, varscan2
- ACTRT2 | c.190T>C p.Y64H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV101007670, COSV65759745; called by muse, mutect2, varscan2
- ACTRT2 | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 71/86 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV101007672; called by muse, mutect2, varscan2
- ACY3 | c.344T>A p.L115Q | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99663152; called by muse, mutect2, varscan2
- ADAM12 | c.1495A>T p.S499C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100901474; called by muse, mutect2, varscan2
- ADAM23 | c.2157G>A p.M719I | Missense Mutation (SNP) | VAF 44/58 reads (76%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV100008788; called by muse, mutect2, varscan2
- ADAM8 | c.2347G>T p.V783L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV101291745; called by muse, mutect2, varscan2
- ADAMTS12 | c.4284G>C p.Q1428H | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100711668; called by muse, mutect2
- ADAMTS12 | c.4120A>T p.S1374C | Missense Mutation (SNP) | VAF 188/290 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100711669; called by muse, mutect2, varscan2
- ADAMTS19 | c.2363G>A p.C788Y | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99180610; called by muse, mutect2, varscan2
- ADAMTS5 | c.1437G>T p.Q479H | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.47); catalogued as COSV99538316; called by muse, mutect2, varscan2
- ADARB2 | c.1463C>A p.S488Y | Missense Mutation (SNP) | VAF 97/193 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101187285, COSV67239703; called by muse, mutect2, varscan2
- ADCY1 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99812882; called by muse, mutect2, varscan2
- ADCY5 | c.2221C>G p.L741V | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV100568236; called by muse, mutect2, varscan2
- ADGRB2 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as COSV99926904; called by muse, mutect2, varscan2
- ADGRG4 | c.7203G>A p.W2401* | Nonsense Mutation (SNP) | VAF 25/40 reads (63%) | catalogued as COSV99796730; called by muse, mutect2, varscan2
- ADGRG4 | c.8648C>A p.T2883N | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV54956478; called by muse, mutect2, varscan2
- ADGRG6 | c.1270C>T p.H424Y | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.259); catalogued as COSV99748641; called by muse, mutect2, varscan2
- ADGRL3 | c.814C>A p.H272N (on ENST00000506720 / NM_001322402.2; = p.H204N on NM_015236.6) | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT tolerated (0.46); PolyPhen benign (0.163); catalogued as COSV101547386; called by muse, mutect2, varscan2
- ADORA1 | c.454G>T p.V152L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99704741; called by muse, mutect2, varscan2
- AFDN | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 158/186 reads (85%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV60043738, COSV60062275; called by muse, mutect2, varscan2
- AGBL1 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.238); catalogued as rs1393963644, COSV101224204, COSV101224356; called by muse, mutect2, varscan2
- AGRN | c.2369C>T p.P790L | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101039071; called by muse, mutect2, varscan2
- AIF1 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100559094; called by muse, mutect2, varscan2
- AK5 | c.145G>T p.G49C (on ENST00000354567 / NM_174858.3; = p.G23C on NM_012093.4) | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100481571; called by muse, mutect2, varscan2
- AK7 | c.1132G>C p.V378L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99967257, COSV99967530; called by muse, mutect2, varscan2
- ALDH2 | c.1393G>T p.A465S | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.692); catalogued as COSV99923276; called by muse, mutect2, varscan2
- ALKBH5 | c.1100A>G p.Y367C | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101213328; called by muse, mutect2, varscan2
- AMER1 | c.520A>T p.S174C | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100366873, COSV100367034; called by muse, mutect2, varscan2
- AMER2 | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63436596; called by muse, mutect2, varscan2
- AMER3 | c.515A>T p.E172V | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100366893; called by muse, mutect2, varscan2
- ANK2 | c.7033G>A p.E2345K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV100004185; called by muse, mutect2, varscan2
- ANKAR | c.1837T>C p.Y613H | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99854627; called by muse, mutect2, varscan2
- ANKRD13C | c.1218G>T p.P406= | Splice Region (SNP) | VAF 24/55 reads (44%) | catalogued as rs34209470; called by muse, mutect2, varscan2
- ANKRD30A | c.3677C>G p.A1226G (on ENST00000611781; = p.A1170G on NM_052997.2) | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV100654224, COSV100654428; called by muse, mutect2, varscan2
- ANKRD46 | c.254G>A p.C85Y | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100170250; called by muse, mutect2, varscan2
- ANO3 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV99885647; called by muse, mutect2, varscan2
- ANO4 | c.747C>A p.H249Q (on ENST00000392977 / NM_001286615.2; = p.H214Q on NM_178826.4) | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV100153785, COSV54595376; called by muse, mutect2, varscan2
- ANTXR1 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 69/113 reads (61%) | catalogued as COSV100363093; called by muse, mutect2, varscan2
- APC | c.8146G>T p.V2716L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs587778044, COSV57373097; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.10535C>A p.T3512N | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs145861016, COSV51948575; called by muse, mutect2, varscan2
- ARFGEF2 | c.2800A>G p.I934V | Missense Mutation (SNP) | VAF 54/70 reads (77%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.463); catalogued as rs1309058613, COSV64216660; called by muse, mutect2, varscan2
- ARHGAP21 | c.1613G>T p.R538L | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.982); catalogued as COSV100256647; called by muse, mutect2, varscan2
- ARHGAP22 | c.391C>G p.R131G | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV99985824, COSV99985994; called by muse, mutect2, varscan2
- ARHGAP22 | c.169C>A p.R57S | Missense Mutation (SNP) | VAF 67/333 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50949153, COSV99986000; called by muse, mutect2, varscan2
- ARHGAP32 | c.4193G>T p.R1398L (on ENST00000310343 / NM_001378025.1; = p.R1049L on NM_014715.4) | Missense Mutation (SNP) | VAF 52/64 reads (81%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.253); catalogued as rs745938491, COSV100089258; called by muse, mutect2, varscan2
- ARHGEF6 | c.1204C>G p.Q402E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV51687097, COSV99166468; called by muse, mutect2, varscan2
- ARMC3 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99958841; called by muse, mutect2, varscan2
- ARMCX1 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100863242; called by muse, mutect2, varscan2
- ARSI | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100156097; called by muse, mutect2, varscan2
- ASAH2 | c.196C>A p.R66S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV100270151; called by muse, mutect2, varscan2
- ASAP2 | c.532A>G p.I178V | Missense Mutation (SNP) | VAF 150/329 reads (46%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.891); catalogued as COSV99856786; called by muse, mutect2, varscan2
- ASIC2 | c.1207C>A p.L403I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99861098; called by muse, mutect2, varscan2
- ASMT | c.580G>T p.A194S (on ENST00000381229; = p.A222S on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/134 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101172539; called by muse, mutect2, varscan2
- ASPA | c.65G>C p.G22A | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52153708, COSV99279399, COSV99279534; called by muse, mutect2, varscan2
- ASPH | c.1552G>T p.G518* | Nonsense Mutation (SNP) | VAF 68/272 reads (25%) | catalogued as COSV101064431, COSV65247644; called by muse, mutect2, varscan2
- ASXL3 | c.2615C>A p.T872K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as rs1344312970, COSV52457939; called by muse, mutect2, varscan2
- ATP10B | c.4270G>T p.G1424W | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as COSV59157549; called by muse, mutect2, varscan2
- ATP2B4 | c.167G>T p.S56I | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV100398031, COSV58178926; called by muse, mutect2, varscan2
- ATP6V0A4 | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.825); catalogued as COSV100023678; called by muse, mutect2, varscan2
- ATP7A | c.2496C>A p.L832= | Splice Region (SNP) | VAF 57/123 reads (46%) | catalogued as COSV100431682; called by muse, mutect2, varscan2
- ATP7A | c.2627G>T p.G876V | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as CM053113, CS112561, COSV100431684; called by muse, mutect2, varscan2
- ATRX | c.5656C>G p.P1886A | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100971419; called by muse, mutect2, varscan2
- B3GALT1 | c.681C>A p.Y227* | Nonsense Mutation (SNP) | VAF 35/81 reads (43%) | catalogued as COSV100003081; called by muse, mutect2, varscan2
- B4GALNT4 | c.2927G>T p.R976L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100327860; called by muse, mutect2
- BBX | c.1439A>T p.E480V | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100361478, COSV100362249; called by muse, mutect2, varscan2
- BCL2L13 | c.1322C>G p.S441C | Missense Mutation (SNP) | VAF 81/170 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.7); catalogued as rs1363877035, COSV100456401; called by muse, mutect2, varscan2
- BFSP2 | c.1219G>T p.A407S | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.446); catalogued as COSV100183929, COSV56591785; called by muse, mutect2, varscan2
- BLK | c.15T>A p.S5R | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.406); catalogued as COSV99377620; called by muse, mutect2, varscan2
- BLOC1S5 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 19/81 reads (23%) | catalogued as COSV99789574; called by muse, mutect2, varscan2
- BMI1 | c.865A>T p.I289F | Missense Mutation (SNP) | VAF 82/165 reads (50%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.123); catalogued as COSV100936499; called by muse, mutect2, varscan2
- BMP10 | c.1039T>A p.Y347N | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54896666, COSV99770604; called by muse, mutect2, varscan2
- BMP2K | c.2918G>C p.R973P | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV99784892, COSV99785427; called by muse, mutect2, varscan2
- BMP3 | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 98/127 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51084396, COSV99262028; called by muse, mutect2, varscan2
- BMPER | c.1798G>C p.E600Q | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99780527; called by muse, mutect2, varscan2
- BMT2 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV99774847; called by muse, mutect2, varscan2
- BNC2 | c.975C>A p.F325L | Missense Mutation (SNP) | VAF 194/224 reads (87%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV101034375; called by muse, mutect2, varscan2
- BNIP1 | c.136A>T p.K46* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV99199449; called by muse, mutect2, varscan2
- BPNT2 | c.356A>T p.Y119F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs750520263, COSV99389253; called by muse, mutect2, varscan2
- BRCA2 | c.3916G>T p.V1306F | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV101204636; called by muse, mutect2
- BSN | c.1060G>C p.G354R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV99609786; called by muse, mutect2, varscan2
- BTAF1 | c.2864C>T p.S955L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99795804; called by muse, mutect2, varscan2
- BTBD3 | c.1294G>T p.G432C | Missense Mutation (SNP) | VAF 188/205 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99656152; called by muse, mutect2, varscan2
- BTN2A2 | c.686T>G p.L229R | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100760593; called by muse, mutect2, varscan2
- BTRC | c.1550A>T p.K517M (on ENST00000370187 / NM_033637.4; = p.K481M on NM_003939.5) | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100927926; called by muse, mutect2, varscan2
- C10orf82 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 21/86 reads (24%) | catalogued as COSV100980163; called by muse, mutect2, varscan2
- C11orf53 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 131/151 reads (87%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as COSV99724899; called by muse, mutect2, varscan2
- C1GALT1 | c.1025G>T p.R342L | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs777844760, COSV99777652; called by muse, mutect2, varscan2
- C1orf94 | c.726G>T p.Q242H (on ENST00000488417 / NM_001134734.2; = p.Q52H on NM_032884.5) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100975222; called by muse, mutect2
- CACNA1E | c.2194G>T p.A732S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100705264; called by muse, mutect2, varscan2
- CACNA1G | c.5816T>A p.I1939N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV100662537; called by muse, mutect2, varscan2
- CACNA1I | c.4823T>C p.L1608P | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100361514; called by muse, mutect2, varscan2
- CACNA2D4 | c.1637G>T p.R546L | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV99766480; called by muse, mutect2, varscan2
- CACNG6 | c.398C>A p.T133K | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99403669; called by muse, mutect2, varscan2
- CALB1 | c.342C>A p.H114Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as COSV55368169, COSV99618561; called by muse, mutect2, varscan2
- CAMTA2 | c.32A>G p.E11G | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100742068; called by muse, mutect2, varscan2
- CAPN9 | c.54C>A p.D18E | Missense Mutation (SNP) | VAF 99/289 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99681105; called by muse, mutect2, varscan2
- CARD11 | c.2958G>T p.K986N | Missense Mutation (SNP) | VAF 79/186 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.482); catalogued as COSV101210948; called by muse, mutect2, varscan2
- CARMIL1 | c.2095C>G p.Q699E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100278807; called by muse, mutect2, varscan2
- CASC3 | c.788A>T p.Y263F | Missense Mutation (SNP) | VAF 66/118 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99230016; called by muse, mutect2, varscan2
- CCDC102B | c.142G>T p.G48W | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100104851; called by muse, mutect2, varscan2
- CCDC170 | c.1399C>A p.Q467K | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99498817; called by muse, mutect2, varscan2
- CCDC30 | c.984G>A p.K328= (on ENST00000340612; = p.K285= on NM_001080850.3) | Splice Region (SNP) | VAF 27/95 reads (28%) | catalogued as COSV100501670; called by muse, mutect2, varscan2
- CCDC85A | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101339556; called by muse, mutect2, varscan2
- CCKAR | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV99810533; called by muse, mutect2, varscan2
- CCL21 | c.144C>G p.Y48* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV99425635, COSV99425646; called by muse, mutect2
- CD163 | c.1820T>A p.L607H | Missense Mutation (SNP) | VAF 74/95 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100776128; called by muse, mutect2, varscan2
- CD163L1 | c.418G>T p.G140* | Nonsense Mutation (SNP) | VAF 68/83 reads (82%) | catalogued as COSV100550648; called by muse, mutect2, varscan2
- CD1C | c.255G>T p.E85D | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV100939459; called by muse, mutect2, varscan2
- CD1C | c.803T>A p.L268Q | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773196926, COSV100939460; called by muse, mutect2, varscan2
- CD93 | c.1348T>A p.F450I | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99849571; called by muse, mutect2, varscan2
- CDH10 | c.1511G>T p.G504V | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100050252; called by muse, mutect2, varscan2
- CDH10 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 43/70 reads (61%) | catalogued as COSV52576048; called by muse, mutect2, varscan2
- CDH17 | c.875T>A p.I292N | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99218001; called by muse, mutect2, varscan2
- CDH18 | c.1579C>A p.L527I | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV56900075, COSV99938322; called by muse, mutect2, varscan2
- CDH18 | c.1023G>T p.K341N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as COSV99933591, COSV99938325; called by muse, mutect2, varscan2
- CDH2 | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99298508; called by muse, mutect2, varscan2
- CDH20 | c.1037A>G p.K346R | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.609); catalogued as COSV99405765; called by muse, mutect2, varscan2
- CDH7 | c.1781G>T p.C594F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100543214; called by muse, mutect2, varscan2
- CDON | c.2485G>T p.G829* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99701966; called by muse, mutect2, varscan2
- CDR1 | c.607T>A p.W203R | Missense Mutation (SNP) | VAF 77/120 reads (64%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.641); catalogued as COSV100983455; called by muse, mutect2, varscan2
- CDRT1 | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as rs750456464, COSV99887891; called by muse, mutect2, varscan2
- CENATAC | c.796C>A p.L266I | Missense Mutation (SNP) | VAF 54/241 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV57723889, COSV57723919; called by muse, mutect2, varscan2
- CENPK | c.597G>A p.K199= | Splice Region (SNP) | VAF 10/23 reads (43%) | catalogued as rs1409007703, COSV99669556; called by muse, mutect2, varscan2
- CEP104 | c.2738G>T p.G913V | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100986730; called by muse, mutect2, varscan2
- CFAP251 | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 49/69 reads (71%) | SIFT tolerated (0.43); PolyPhen benign (0.046); catalogued as COSV99996475; called by muse, mutect2, varscan2
- CFAP43 | c.1391C>A p.P464H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99531000; called by muse, mutect2, varscan2
- CFAP46 | c.5685G>T p.Q1895H | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.465); catalogued as COSV99585540; called by muse, mutect2, varscan2
- CFAP47 | c.289T>A p.S97T | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.69); catalogued as COSV99935819; called by muse, mutect2, varscan2
- CFH | c.2796A>T p.K932N | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.72); catalogued as COSV100810161; called by muse, mutect2, varscan2
- CFHR3 | c.338C>G p.A113G | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.48); PolyPhen benign (0.21); catalogued as COSV100807771; called by muse, mutect2, varscan2
- CHD3 | c.3994G>C p.D1332H | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100391679; called by muse, mutect2, varscan2
- CHD5 | c.1357G>A p.G453S | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99314994; called by muse, mutect2, varscan2
- CHD7 | c.203A>G p.H68R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.95); catalogued as rs771073528, COSV101418436; called by muse, mutect2, varscan2
- CHL1 | c.3204A>T p.R1068S (on ENST00000397491 / NM_001253387.1; = p.R1084S on NM_006614.4) | Missense Mutation (SNP) | VAF 68/87 reads (78%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV99852296; called by muse, mutect2, varscan2
- CHM | c.1166+1G>C p.X389_splice | Splice Site (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100753638; called by muse, mutect2
- CHM | c.649T>A p.Y217N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100753639; called by muse, mutect2
- CHM | c.647C>A p.T216N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100753640; called by muse, mutect2
- CHRD | c.2176T>C p.C726R | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99200791; called by muse, mutect2, varscan2
- CHRNA10 | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.176); catalogued as COSV99167253; called by muse, mutect2, varscan2
- CHRNA6 | c.1329G>A p.M443I | Missense Mutation (SNP) | VAF 332/469 reads (71%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as rs752232974, COSV52380001; called by muse, mutect2, varscan2
- CLCN1 | c.1220C>A p.P407Q | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58367238; called by muse, mutect2, varscan2
- CLEC9A | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV100872870; called by muse, mutect2, varscan2
- CLIP1 | c.97G>T p.V33L | Missense Mutation (SNP) | VAF 111/138 reads (80%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100212368; called by muse, mutect2, varscan2
- CLPTM1L | c.1595C>T p.T532M | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs770025461, COSV57989090; called by muse, mutect2, varscan2
- CLTCL1 | c.2087A>T p.Q696L | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV99595853; called by muse, mutect2, varscan2
- CLVS2 | c.377G>T p.W126L | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99253526; called by muse, mutect2, varscan2
- CMTR2 | c.1606A>T p.K536* | Nonsense Mutation (SNP) | VAF 30/39 reads (77%) | catalogued as COSV100579348; called by muse, mutect2, varscan2
- CNBD1 | c.673G>C p.D225H | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as COSV101575302; called by muse, mutect2, varscan2
- CNGA3 | c.1322T>G p.F441C | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV99737442; called by muse, mutect2, varscan2
- CNN1 | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99372525; called by muse, mutect2, varscan2
- CNTN2 | c.509T>A p.L170H | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100085464; called by muse, mutect2, varscan2
- CNTNAP4 | c.2236T>C p.W746R | Missense Mutation (SNP) | VAF 70/90 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV100273309; called by muse, mutect2, varscan2
- COG6 | c.1953A>T p.Q651H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100743345; called by muse, mutect2, varscan2
- COL26A1 | c.484C>T p.P162S (on ENST00000313669 / NM_001278563.3; = p.P160S on NM_133457.4) | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.78); PolyPhen benign (0.062); catalogued as COSV100562043; called by muse, mutect2, varscan2
- COL27A1 | c.3959T>G p.L1320R | Missense Mutation (SNP) | VAF 73/104 reads (70%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV100621319; called by muse, mutect2, varscan2
- COL4A5 | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100089849; called by muse, mutect2, varscan2
- COL6A3 | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.12); PolyPhen benign (0.196); catalogued as COSV99801360; called by muse, mutect2, varscan2
- COLEC12 | c.1954C>A p.Q652K | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.868); catalogued as COSV101232165; called by muse, mutect2, varscan2
- COLEC12 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs772829011, COSV101232166; called by muse, mutect2
- COQ7 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100430574; called by muse, mutect2
- CORO1B | c.229A>T p.T77S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.491); catalogued as COSV100396763; called by muse, mutect2, varscan2
- CPSF3 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs757160812, COSV53009954; called by muse, mutect2, varscan2
- CR1L | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54324386, COSV99687997; called by muse, mutect2
- CRHBP | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99169535; called by muse, mutect2, varscan2
- CRIPT | c.70A>T p.R24W | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99482816; called by muse, mutect2, varscan2
- CRISP2 | c.44C>A p.P15Q | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.12); catalogued as COSV100189234; called by muse, mutect2, varscan2
- CRISP2 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 62/123 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100189237; called by muse, mutect2, varscan2
- CRYBA2 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as COSV99838145; called by muse, mutect2, varscan2
- CSGALNACT2 | c.843A>T p.R281S | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100989851; called by muse, mutect2
- CSMD2 | c.8297C>A p.T2766N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.978); catalogued as COSV99586211; called by muse, mutect2, varscan2
- CSMD2 | c.5411G>T p.R1804M | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV99595132; called by muse, mutect2, varscan2
- CSMD3 | c.10270G>T p.G3424W (on ENST00000297405 / NM_001363185.1; = p.G3255W on NM_052900.3) | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99838718; called by muse, mutect2, varscan2
- CSMD3 | c.7904_7905insA p.K2636* (on ENST00000297405 / NM_001363185.1; = p.K2532* on NM_052900.3) | Frame Shift Ins (INS) | VAF 14/62 reads (23%) | catalogued as COSV99847256; called by mutect2, pindel, varscan2
- CSMD3 | c.6874G>T p.G2292C (on ENST00000297405 / NM_001363185.1; = p.G2188C on NM_052900.3) | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52168679; called by muse, mutect2, varscan2
- CSMD3 | c.5873C>A p.P1958H (on ENST00000297405 / NM_001363185.1; = p.P1854H on NM_052900.3) | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52188668; called by muse, mutect2, varscan2
- CSMD3 | c.5391G>T p.E1797D (on ENST00000297405 / NM_001363185.1; = p.E1693D on NM_052900.3) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV99847261; called by muse, mutect2, varscan2
- CSMD3 | c.3070C>G p.H1024D (on ENST00000297405 / NM_001363185.1; = p.H920D on NM_052900.3) | Missense Mutation (SNP) | VAF 125/193 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.158); catalogued as COSV52219274, COSV99847264; called by muse, mutect2, varscan2
- CSPG4 | c.804G>T p.Q268H | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100414140; called by muse, mutect2, varscan2
- CTNNA2 | c.820G>C p.G274R | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100786127, COSV63548356; called by muse, mutect2, varscan2
- CTNNA2 | c.1681T>C p.Y561H | Missense Mutation (SNP) | VAF 47/242 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100562004; called by muse, mutect2, varscan2
- CTNNA3 | c.167G>T p.S56I | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99042802; called by muse, mutect2, varscan2
- CTNND2 | c.2789G>T p.G930V | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100480938; called by muse, mutect2, varscan2
- CTNND2 | c.2789-1G>T p.X930_splice | Splice Site (SNP) | VAF 38/63 reads (60%) | catalogued as COSV100480941; called by muse, mutect2, varscan2
- CTSF | c.668C>G p.A223G | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT tolerated (0.08); PolyPhen benign (0.216); catalogued as COSV100074496; called by muse, mutect2, varscan2
- CUL1 | c.2150G>C p.R717T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100296926; called by muse, mutect2, varscan2
- CXorf66 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 46/69 reads (67%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV100983945; called by muse, mutect2, varscan2
- CYB5R4 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100859756; called by muse, mutect2
- CYTL1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.77); catalogued as rs1018761416, COSV100312522; called by muse, mutect2, varscan2
- DACH2 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV100914085, COSV64171805; called by muse, mutect2
- DCAF12L2 | c.659G>T p.W220L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100758842; called by muse, varscan2
- DCAF8 | c.150G>T p.L50F | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.289); catalogued as COSV100470796; called by muse, mutect2
- DCDC1 | c.4955G>T p.R1652L (on ENST00000597505 / NM_001367979.1; = p.R759L on NM_020869.3) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.027); catalogued as COSV100360782; called by muse, mutect2, varscan2
- DCDC2 | c.1180C>G p.H394D | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV101015538; called by muse, mutect2, varscan2
- DDX39A | c.389A>G p.K130R | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV99660517; called by muse, mutect2, varscan2
- DDX60 | c.3699C>A p.D1233E | Missense Mutation (SNP) | VAF 93/116 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV101190651; called by muse, mutect2, varscan2
- DEFA6 | c.239C>A p.S80* | Nonsense Mutation (SNP) | VAF 25/37 reads (68%) | catalogued as COSV52406417, COSV99857915; called by muse, mutect2, varscan2
- DGKI | c.756C>G p.H252Q | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99937177; called by muse, mutect2, varscan2
- DGKI | c.532C>A p.H178N | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV99937180; called by muse, mutect2, varscan2
- DHPS | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99269550, COSV99269754; called by muse, mutect2, varscan2
- DIP2C | c.3091G>T p.A1031S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99793719; called by muse, mutect2, varscan2
- DLGAP3 | c.2519C>T p.T840I | Missense Mutation (SNP) | VAF 111/211 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV99333164; called by muse, mutect2, varscan2
- DMD | c.9175G>A p.G3059S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.765); catalogued as COSV100629272; called by muse, mutect2, varscan2
- DMD | c.7990G>T p.E2664* | Nonsense Mutation (SNP) | VAF 17/29 reads (59%) | catalogued as COSV100629274; called by muse, mutect2, varscan2
- DMRTB1 | c.826C>A p.P276T | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.431); catalogued as COSV101008403; called by muse, mutect2, varscan2
- DNAH10 | c.4094C>G p.A1365G (on ENST00000409039; = p.A1304G on NM_207437.3) | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101292699; called by muse, mutect2, varscan2
- DNAH11 | c.8551G>C p.A2851P | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1182105537, COSV100180802, COSV60939941; called by muse, mutect2, varscan2
- DNAH2 | c.1975G>T p.V659L | Missense Mutation (SNP) | VAF 141/292 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV101209587; called by muse, mutect2, varscan2
- DNAJC6 | c.1652G>T p.S551I | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV99675617; called by muse, mutect2
- DOCK2 | c.4294A>C p.N1432H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs1244831224, COSV99915313; called by muse, mutect2, varscan2
- DOCK2 | c.4993A>T p.S1665C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV99915316; called by muse, mutect2, varscan2
- DOCK8 | c.4840A>T p.R1614W | Missense Mutation (SNP) | VAF 73/95 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV101210074; called by muse, mutect2, varscan2
- DOP1B | c.445G>T p.V149L | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV99536041; called by muse, mutect2, varscan2
- DPAGT1 | c.764G>T p.C255F | Missense Mutation (SNP) | VAF 83/189 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99598185; called by muse, mutect2, varscan2
- DPP10 | c.302G>C p.G101A | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100071628, COSV59694727; called by muse, mutect2, varscan2
- DPYS | c.410G>T p.W137L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.977); catalogued as COSV100680103; called by muse, mutect2, varscan2
- DRD1 | c.92C>A p.S31* | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | catalogued as COSV101192522, COSV67104817; called by muse, mutect2, varscan2
- DROSHA | c.3209A>T p.N1070I | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV100757817; called by muse, mutect2, varscan2
- DSCAML1 | c.4638C>G p.H1546Q (on ENST00000321322; = p.H1486Q on NM_020693.4) | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.713); catalogued as COSV100357216, COSV58382706; called by muse, mutect2, varscan2
- DSG1 | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV99936557; called by muse, mutect2, varscan2
- DST | c.8074G>C p.A2692P | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV99759847; called by muse, mutect2, varscan2
- DST | c.7123A>T p.S2375C | Missense Mutation (SNP) | VAF 74/122 reads (61%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as COSV99759851; called by muse, mutect2, varscan2
- DYNC2H1 | c.2771A>G p.Q924R | Missense Mutation (SNP) | VAF 63/70 reads (90%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV100519703, COSV62106599; called by muse, mutect2, varscan2
- E2F4 | c.682C>G p.L228V | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.057); catalogued as COSV58875513; called by muse, mutect2, varscan2
- ECRG4 | c.415C>A p.H139N | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs767390809, COSV99430535; called by muse, mutect2
- EDA2R | c.839A>G p.E280G | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99490975; called by muse, mutect2, varscan2
- EDIL3 | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.06); catalogued as COSV99679087; called by muse, mutect2, varscan2
- EGFLAM | c.2471G>A p.G824E | Missense Mutation (SNP) | VAF 169/271 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100380779; called by muse, mutect2, varscan2
- EHBP1 | c.2806G>T p.D936Y | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99861859; called by muse, mutect2, varscan2
- EHMT1 | c.1750A>G p.K584E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as COSV100604244; called by muse, mutect2, varscan2
- ENO1 | c.180G>A p.K60= | Splice Region (SNP) | VAF 27/111 reads (24%) | catalogued as COSV99319004; called by muse, mutect2, varscan2
- ENPEP | c.2305G>T p.E769* | Nonsense Mutation (SNP) | VAF 73/97 reads (75%) | catalogued as COSV99488115; called by muse, mutect2, varscan2
- ENPEP | c.2477T>C p.V826A | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV99488117; called by muse, mutect2, varscan2
- EOLA1 | c.284G>T p.C95F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV63734167; called by muse, mutect2, varscan2
- EPB41L2 | c.392A>T p.E131V | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV100441379; called by muse, mutect2
- EPB41L3 | c.1987T>G p.C663G | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100550206; called by muse, mutect2, varscan2
- EPCAM | c.184+1G>T p.X62_splice | Splice Site (SNP) | VAF 19/36 reads (53%) | catalogued as rs866758817, COSV55392638, COSV99764316; called by muse, mutect2, varscan2
- EPHB6 | c.2867C>A p.A956D | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.739); catalogued as COSV100844432; called by muse, mutect2, varscan2
- ERBB4 | c.3538C>A p.L1180I | Missense Mutation (SNP) | VAF 66/89 reads (74%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs764925334, COSV100727557; called by muse, mutect2, varscan2
- ERLIN1 | c.867G>T p.Q289H | Missense Mutation (SNP) | VAF 57/103 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as CD140972, COSV100962327; called by muse, mutect2, varscan2
- EVX2 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV100420833; called by muse, mutect2, varscan2
- F13B | c.1361G>A p.C454Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781560458, COSV100803288, COSV100803445; called by muse, mutect2, varscan2
- F8 | c.705G>C p.L235F | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV99068161; called by muse, mutect2, varscan2
- FAAH | c.952G>T p.V318F | Missense Mutation (SNP) | VAF 120/411 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV99680287; called by muse, mutect2, varscan2
- FABP3 | c.20G>C p.G7A | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as COSV101038456; called by muse, mutect2, varscan2
- FAM135B | c.3703T>A p.Y1235N | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99427459; called by muse, mutect2, varscan2
- FAM153A | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 64/203 reads (32%) | catalogued as COSV100647120; called by muse, mutect2, varscan2
- FAM167B | c.295G>C p.G99R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1457559720, COSV100405968; called by muse, mutect2, varscan2
- FAM189B | c.1867G>T p.E623* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100516463; called by muse, mutect2, varscan2
- FAM221A | c.251A>G p.H84R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100794387; called by muse, mutect2
- FAM47A | c.2276C>G p.A759G | Missense Mutation (SNP) | VAF 99/118 reads (84%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV100650065; called by muse, mutect2, varscan2
- FAM47A | c.1104G>T p.K368N | Missense Mutation (SNP) | VAF 62/80 reads (78%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV100650066; called by muse, mutect2, varscan2
- FARSA | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99536170; called by muse, mutect2, varscan2
- FAT1 | c.13559C>A p.P4520Q | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as COSV101499637; called by muse, mutect2, varscan2
- FAT2 | c.7897G>T p.V2633F | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.501); catalogued as COSV99944074; called by muse, mutect2, varscan2
- FAT2 | c.5522A>C p.Y1841S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.129); catalogued as COSV99944077; called by muse, mutect2, varscan2
- FAT2 | c.4142G>T p.W1381L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.475); catalogued as COSV99942764, COSV99944079; called by muse, mutect2, varscan2
- FBN1 | c.2600A>T p.N867I | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs145464311, COSV100356381; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN2 | c.5930G>A p.C1977Y | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV99330571; called by muse, mutect2, varscan2
- FCHO2 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as rs887520336, COSV99822084; called by muse, mutect2, varscan2
- FCRL1 | c.716T>A p.L239Q | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as COSV100839894; called by muse, mutect2, varscan2
- FCRL1 | c.593G>T p.S198I | Missense Mutation (SNP) | VAF 46/310 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as COSV100839896; called by muse, mutect2, varscan2
- FCRL2 | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 136/251 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100830002; called by muse, mutect2, varscan2
- FCRL2 | c.695C>T p.T232I | Missense Mutation (SNP) | VAF 224/432 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs769609452, COSV100829963, COSV100830003; called by muse, mutect2, varscan2
- FCRL3 | c.1109C>A p.T370K | Missense Mutation (SNP) | VAF 94/168 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100943539; called by muse, mutect2, varscan2
- FER1L6 | c.4489G>T p.G1497W | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101206180, COSV67553233; called by muse, mutect2, varscan2
- FER1L6 | c.4490G>T p.G1497V | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101206181, COSV67549214; called by muse, mutect2, varscan2
- FGD5 | c.3974C>A p.P1325H | Missense Mutation (SNP) | VAF 62/80 reads (78%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.525); catalogued as rs760701817, COSV53251069, COSV99549225; called by muse, mutect2, varscan2
- FGF14 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV65949591; called by muse, mutect2, varscan2
- FGF6 | c.380T>G p.V127G | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99960422; called by muse, mutect2
- FIZ1 | c.1431G>T p.K477N | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99684737; called by muse, mutect2, varscan2
- FLG2 | c.3585T>A p.H1195Q | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV101166212; called by muse, mutect2, varscan2
- FNDC3A | c.2468C>G p.T823S (on ENST00000492622 / NM_001079673.2; = p.T767S on NM_014923.5) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV101256963; called by muse, mutect2, varscan2
- FOXD4 | c.217G>C p.G73R | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as COSV100071274; called by muse, mutect2, varscan2
- FPGT | c.489G>T p.M163I | Missense Mutation (SNP) | VAF 61/74 reads (82%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV100907527; called by muse, mutect2, varscan2
- FRG1 | c.720G>T p.L240F | Missense Mutation (SNP) | VAF 162/217 reads (75%) | SIFT tolerated (0.32); PolyPhen benign (0.06); catalogued as COSV56996327, COSV99903935; called by muse, mutect2, varscan2
- FSCB | c.734A>G p.E245G | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV100469860; called by muse, mutect2, varscan2
- FTH1 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as COSV99861403; called by muse, mutect2, varscan2
- FTMT | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs748280112; called by muse, varscan2
- FYB2 | c.1235C>A p.A412D | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as COSV100599781; called by muse, mutect2, varscan2
- GAB4 | c.1309C>A p.L437M | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101272103; called by muse, mutect2, varscan2
- GABRA4 | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99974687; called by muse, mutect2, varscan2
- GABRG2 | c.1423C>T p.H475Y (on ENST00000361925 / NM_001375343.1; = p.H435Y on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.98); catalogued as COSV100729847; called by muse, mutect2, varscan2
- GALNT14 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 156/391 reads (40%) | catalogued as COSV100205565; called by muse, mutect2, varscan2
- GALNT15 | c.695T>A p.L232H | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100328010; called by muse, mutect2, varscan2
- GALNT5 | c.2718A>T p.L906F | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.972); catalogued as COSV99375587; called by muse, mutect2, varscan2
- GBP5 | c.793A>T p.T265S | Missense Mutation (SNP) | VAF 75/88 reads (85%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100600167; called by muse, mutect2, varscan2
- GBP7 | c.1573G>C p.E525Q | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99643489; called by muse, mutect2, varscan2
- GCC1 | c.1909G>T p.D637Y | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100365661; called by muse, mutect2, varscan2
- GDNF | c.636A>T p.*212Cext*32 | Nonstop Mutation (SNP) | VAF 35/95 reads (37%) | catalogued as COSV100427557; called by muse, mutect2, varscan2
- GGCX | c.1039A>T p.R347W | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99290184; called by muse, mutect2, varscan2
- GHR | c.1678T>A p.L560I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.099); catalogued as COSV100051984; called by muse, mutect2, varscan2
- GHSR | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as COSV99577248; called by muse, mutect2, varscan2
- GIMAP2 | c.204G>C p.W68C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56235254, COSV99785528; called by muse, mutect2, varscan2
- GIMAP8 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.069); catalogued as rs200592029, COSV56232852, COSV56235726; called by muse, mutect2, varscan2
- GIMAP8 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as COSV100217699, COSV56229507, COSV56233783; called by muse, mutect2, varscan2
- GLB1L3 | c.1499G>T p.R500M | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV101345158; called by muse, mutect2, varscan2
- GLI2 | c.3877G>T p.A1293S (on ENST00000361492 / NM_001374353.1; = p.A1310S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.025); catalogued as COSV100084293; called by mutect2, varscan2
- GLT6D1 | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 60/70 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV100874591; called by muse, mutect2, varscan2
- GOLT1B | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99982119; called by muse, mutect2, varscan2
- GPHN | c.940A>G p.R314G (on ENST00000315266 / NM_001377519.1; = p.R347G on NM_020806.5) | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100017667; called by muse, mutect2, varscan2
- GPR148 | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as COSV99998733; called by muse, mutect2, varscan2
- GPR15 | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV99423948; called by muse, mutect2, varscan2
- GPR156 | c.1484A>G p.Q495R | Missense Mutation (SNP) | VAF 125/148 reads (84%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as COSV100251711; called by muse, mutect2, varscan2
- GPRASP2 | c.1223A>T p.E408V | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV100176939; called by muse, mutect2, varscan2
- GRIK1 | c.2048T>G p.I683R | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760063205, COSV100517902; called by muse, mutect2, varscan2
- GRIK1 | c.1908G>T p.Q636H | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100517905; called by muse, mutect2, varscan2
- GRIN3B | c.2351C>A p.T784N | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99312903; called by muse, mutect2, varscan2
- GRM1 | c.2953G>A p.A985T | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV99265408; called by muse, mutect2
- GRM2 | c.1658G>T p.C553F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99623152; called by muse, mutect2, varscan2
- GRM4 | c.2637C>G p.F879L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100946873, COSV65211213; called by muse, mutect2, varscan2
- GRM7 | c.2487G>T p.M829I | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.932); catalogued as COSV100738528; called by muse, mutect2, varscan2
- GSDME | c.650T>A p.I217N | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100742438; called by muse, mutect2
- GSX2 | c.713A>T p.Y238F | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV100482622; called by muse, mutect2, varscan2
- GTSE1 | c.928-1G>T p.X310_splice | Splice Site (SNP) | VAF 34/130 reads (26%) | catalogued as COSV101483255; called by muse, mutect2, varscan2
- H3C2 | c.126C>A p.Y42* | Nonsense Mutation (SNP) | VAF 84/300 reads (28%) | catalogued as COSV52518044; called by muse, mutect2, varscan2
- H4C13 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.83); catalogued as COSV100138081; called by muse, mutect2
- HAPLN1 | c.659C>G p.T220R | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.178); catalogued as COSV99165198; called by muse, mutect2, varscan2
- HDAC9 | c.383G>T p.R128I | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV101287488; called by muse, mutect2, varscan2
- HDX | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99948021; called by muse, mutect2, varscan2
- HECW1 | c.1787A>G p.E596G | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.054); catalogued as COSV101224278; called by muse, mutect2
- HECW1 | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as rs771147604, COSV67834314; called by muse, mutect2, varscan2
- HEPACAM | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 52/62 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV100005924; called by muse, mutect2, varscan2
- HERC2 | c.8938A>G p.I2980V | Missense Mutation (SNP) | VAF 41/58 reads (71%) | SIFT tolerated (0.3); PolyPhen benign (0.138); catalogued as COSV99876656; called by muse, mutect2, varscan2
- HEY2 | c.56A>T p.D19V | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV100856431; called by muse, mutect2, varscan2
- HHIP | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99667853; called by muse, mutect2, varscan2
- HINFP | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100640848, COSV100640887; called by muse, mutect2, varscan2
- HIVEP3 | c.1810G>T p.E604* | Nonsense Mutation (SNP) | VAF 38/128 reads (30%) | catalogued as rs764327869, COSV56017039, COSV56021277, COSV99913969; called by muse, mutect2, varscan2
- HLX | c.938T>C p.L313P | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100854469; called by muse, mutect2, varscan2
- HMGN5 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100815020; called by muse, mutect2, varscan2
- HOXA7 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 147/292 reads (50%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99636755; called by muse, mutect2, varscan2
- HOXD3 | c.737G>T p.R246L | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50879425, COSV99980406; called by muse, mutect2, varscan2
- HPGDS | c.35G>A p.R12K | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV99756068; called by muse, mutect2, varscan2
- HRH1 | c.1131G>T p.R377S | Missense Mutation (SNP) | VAF 53/64 reads (83%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV101229112; called by muse, mutect2, varscan2
- HRH2 | c.577C>A p.L193I | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV99199910; called by muse, mutect2, varscan2
- HSD17B2 | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV99556819; called by muse, mutect2, varscan2
- IDS | c.562G>T p.V188L | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as COSV100558186; called by muse, mutect2, varscan2
- IFITM1 | c.146G>A p.W49* | Nonsense Mutation (SNP) | VAF 54/149 reads (36%) | catalogued as COSV100068323; called by muse, mutect2, varscan2
- IFNAR2 | c.424G>C p.V142L | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV100577168; called by muse, mutect2, varscan2
- IFNL3 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV101308029; called by muse, mutect2, varscan2
- IGSF9 | c.1298G>T p.G433V (on ENST00000368094 / NM_001135050.2; = p.G417V on NM_020789.4) | Missense Mutation (SNP) | VAF 90/132 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100829660; called by muse, mutect2, varscan2
- IGSF9B | c.3932G>T p.G1311V | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.169); catalogued as COSV100318407; called by mutect2, varscan2
- IL12RB1 | c.1562G>T p.R521L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101651918; called by muse, mutect2, varscan2
- IL1RL1 | c.822A>G p.Q274= | Splice Region (SNP) | VAF 32/152 reads (21%) | catalogued as COSV99294535; called by muse, mutect2, varscan2
- IL2RB | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99345138; called by muse, mutect2, varscan2
- IL31RA | c.1643-1G>T p.X548_splice | Splice Site (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99763567; called by muse, mutect2, varscan2
- IL5RA | c.640C>A p.L214I | Missense Mutation (SNP) | VAF 48/70 reads (69%) | SIFT tolerated (0.45); PolyPhen benign (0.115); catalogued as rs369877234; called by muse, mutect2, varscan2
- IL7R | c.58G>T p.G20* | Nonsense Mutation (SNP) | VAF 100/199 reads (50%) | catalogued as COSV100286645; called by muse, mutect2, varscan2
- IMPACT | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 147/223 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99408910; called by muse, mutect2, varscan2
- IPO9 | c.811-2A>T p.X271_splice | Splice Site (SNP) | VAF 52/90 reads (58%) | catalogued as COSV100843563; called by muse, mutect2, varscan2
- IRAK1 | c.378G>T p.E126D | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.078); catalogued as COSV100318492; called by muse, mutect2, varscan2
- ISM1 | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 84/110 reads (76%) | SIFT tolerated (0.2); PolyPhen benign (0.065); catalogued as COSV99340324; called by muse, mutect2, varscan2
- ITGA1 | c.443G>C p.C148S | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200986699, COSV99252139; called by muse, mutect2, varscan2
- ITGA2B | c.2944-1G>T p.X982_splice | Splice Site (SNP) | VAF 29/132 reads (22%) | catalogued as COSV99289256; called by muse, mutect2, varscan2
- ITGAX | c.2494G>T p.V832L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV51642495, COSV99192028; called by muse, mutect2, varscan2
- ITIH6 | c.3047C>G p.S1016C | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV99512874, COSV99513956; called by muse, mutect2, varscan2
- ITPRID1 | c.2218T>A p.C740S | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.372); catalogued as COSV100087483; called by muse, mutect2, varscan2
- ITPRID2 | c.742A>T p.T248S | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100238731; called by muse, mutect2, varscan2
- IYD | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs369994249; called by muse, mutect2, varscan2
- JMJD1C | c.5581C>A p.Q1861K | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.12); catalogued as COSV100550831; called by muse, mutect2, varscan2
- KAT2B | c.1381A>T p.I461F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99769887; called by muse, mutect2, varscan2
- KCNA1 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 49/65 reads (75%) | catalogued as COSV101230355; called by muse, mutect2, varscan2
- KCNA1 | c.1447C>A p.Q483K | Missense Mutation (SNP) | VAF 120/146 reads (82%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.028); catalogued as COSV101230356; called by muse, mutect2, varscan2
- KCNB2 | c.1491G>C p.K497N | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV101579003, COSV73051439; called by muse, mutect2, varscan2
- KCNC2 | c.587C>A p.A196E | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.26); PolyPhen benign (0.324); catalogued as COSV100129849, COSV54365172; called by muse, mutect2, varscan2
- KCNJ5 | c.1094A>T p.K365M | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100610807; called by muse, mutect2, varscan2
- KCNK12 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100010042; called by muse, mutect2, varscan2
- KCNK9 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100271690, COSV57278431; called by muse, mutect2, varscan2
- KCNMB1 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.871); catalogued as COSV99212029; called by muse, mutect2, varscan2
- KCNS2 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54639855; called by muse, mutect2, varscan2
- KDM4C | c.1142A>T p.K381I | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV101185135; called by muse, mutect2, varscan2
- KDM6A | c.747A>C p.L249F | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100938569; called by muse, mutect2, varscan2
- KDR | c.2890G>T p.D964Y | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99818620; called by muse, mutect2, varscan2
- KIAA0319L | c.1970G>T p.G657V | Missense Mutation (SNP) | VAF 105/201 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100357687; called by muse, mutect2, varscan2
- KIAA1109 | c.11519A>T p.K3840M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99175310; called by muse, mutect2, varscan2
- KIF21A | c.1825G>T p.D609Y (on ENST00000361418 / NM_001378440.1; = p.D596Y on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV100735642; called by muse, mutect2, varscan2
- KIR2DL4 | c.390C>A p.H130Q (on ENST00000396284; = p.H91Q on NM_001080770.2) | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.384); catalogued as COSV100610566; called by muse, varscan2
- KITLG | c.734C>G p.T245R | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.679); catalogued as rs904965794, COSV99933553; called by muse, mutect2, varscan2
- KLF7 | c.648G>T p.K216N | Missense Mutation (SNP) | VAF 96/116 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100519390; called by muse, mutect2, varscan2
- KLHL1 | c.157C>A p.Q53K | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.678); catalogued as COSV100918127; called by muse, mutect2, varscan2
- KLHL11 | c.1213A>G p.T405A | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.138); catalogued as COSV100044469; called by muse, mutect2, varscan2
- KLHL14 | c.547G>T p.V183L | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.029); catalogued as COSV100809286; called by muse, mutect2, varscan2
- KLHL31 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 113/217 reads (52%) | catalogued as COSV100911854; called by muse, mutect2, varscan2
- KLHL4 | c.213C>A p.H71Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.021); catalogued as COSV100910159; called by muse, mutect2, varscan2
- KPRP | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.124); catalogued as COSV100908800, COSV64221071; called by muse, mutect2, varscan2
- KRT12 | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99289133; called by muse, mutect2
- KRT26 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100156614; called by muse, mutect2, varscan2
- KRT76 | c.1322A>T p.K441M | Missense Mutation (SNP) | VAF 60/82 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100196515; called by muse, varscan2
- KRT76 | c.1293G>T p.E431D | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.139); catalogued as COSV100196519, COSV60119368; called by muse, varscan2
- KRTAP10-1 | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 116/302 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100555439; called by muse, mutect2
- KRTAP12-2 | c.164G>T p.C55F | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV100555441; called by muse, mutect2, varscan2
- KRTAP13-2 | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV101299671; called by muse, mutect2, varscan2
- KRTAP13-3 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100481832; called by muse, mutect2, varscan2
- KRTAP13-4 | c.17G>C p.C6S | Missense Mutation (SNP) | VAF 97/262 reads (37%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as COSV100481834; called by muse, varscan2
- KRTAP13-4 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100481767; called by muse, varscan2
- KRTAP15-1 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100481660; called by muse, mutect2, varscan2
- KRTAP4-5 | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100576839; called by muse, mutect2, varscan2
- L1CAM | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 20/31 reads (65%) | catalogued as COSV100649465; called by muse, mutect2, varscan2
- L3MBTL1 | c.1763A>T p.H588L (on ENST00000418998 / NM_001377303.1; = p.H498L on NM_015478.7) | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.863); catalogued as COSV100917060; called by muse, mutect2, varscan2
- LAMA2 | c.3498C>A p.C1166* | Nonsense Mutation (SNP) | VAF 52/56 reads (93%) | catalogued as COSV101370825; called by muse, mutect2, varscan2
- LAMA4 | c.3057C>A p.Y1019* (on ENST00000230538 / NM_001105206.3; = p.Y1012* on NM_002290.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 46/58 reads (79%) | catalogued as COSV100039423; called by muse, mutect2, varscan2
- LAMC1 | c.3074G>A p.W1025* | Nonsense Mutation (SNP) | VAF 40/48 reads (83%) | catalogued as COSV99280423; called by muse, mutect2, varscan2
- LAMC1 | c.3075G>T p.W1025C | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.738); catalogued as COSV99280427; called by muse, mutect2, varscan2
- LCE2B | c.235C>A p.R79S | Missense Mutation (SNP) | VAF 205/376 reads (55%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs759523297, COSV100909340, COSV64228104; called by muse, mutect2, varscan2
- LCE2C | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 129/253 reads (51%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.349); catalogued as COSV100909477; called by muse, mutect2, varscan2
- LCK | c.105G>T p.T35= | Splice Region (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100288136, COSV60742686; called by muse, mutect2, varscan2
- LCOR | c.1013A>C p.Q338P | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100603873; called by muse, mutect2, varscan2
- LGALS12 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99737347; called by muse, mutect2, varscan2
- LIFR | c.1668G>T p.W556C | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99665481; called by muse, mutect2, varscan2
- LILRB5 | c.1502C>A p.A501E (on ENST00000449561 / NM_001081442.3; = p.A500E on NM_006840.5) | Missense Mutation (SNP) | VAF 67/89 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.136); catalogued as COSV100300805, COSV60258408; called by muse, mutect2, varscan2
- LINGO2 | c.144G>T p.L48F | Missense Mutation (SNP) | VAF 65/83 reads (78%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); catalogued as COSV100431214; called by muse, mutect2, varscan2
- LPAR4 | c.909C>A p.N303K | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70913310; called by muse, mutect2, varscan2
- LPIN2 | c.1556A>G p.Y519C | Missense Mutation (SNP) | VAF 73/127 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55245233; called by muse, mutect2, varscan2
- LRIT1 | c.1808C>G p.S603C | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100928152, COSV64512304; called by muse, mutect2
- LRP12 | c.1388G>T p.C463F | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99408336; called by muse, mutect2, varscan2
- LRP1B | c.11882G>T p.S3961I | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV101260831; called by muse, mutect2, varscan2
- LRP1B | c.6541A>C p.T2181P | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV101260833, COSV67262699; called by muse, mutect2
- LRP1B | c.6232G>A p.V2078M | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV101260835, COSV67265353; called by muse, mutect2, varscan2
- LRP1B | c.4100C>A p.S1367Y | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV101260836; called by muse, mutect2, varscan2
- LRP1B | c.3692A>G p.H1231R | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV101260837, COSV67252739; called by muse, mutect2, varscan2
- LRP1B | c.3348T>G p.C1116W | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101260838; called by muse, mutect2, varscan2
- LRP2 | c.9521A>T p.Y3174F | Missense Mutation (SNP) | VAF 105/221 reads (48%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.596); catalogued as COSV99790221; called by muse, mutect2, varscan2
- LRRC43 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 86/108 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100336946; called by muse, mutect2, varscan2
- LRRC45 | c.789G>T p.M263I | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV100141959; called by muse, mutect2, varscan2
- LRRC52 | c.692C>A p.P231Q | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.031); catalogued as COSV99674113; called by muse, mutect2, varscan2
- LRRTM1 | c.493A>C p.T165P | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.834); catalogued as COSV99703172; called by muse, varscan2
- LRRTM1 | c.406A>T p.M136L | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99703173; called by muse, varscan2
- LRRTM4 | c.1757A>G p.E586G | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV101299324; called by muse, mutect2, varscan2
- LRRTM4 | c.521T>A p.I174K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV101297732; called by muse, mutect2, varscan2
- LTBP1 | c.1107C>A p.S369R (on ENST00000404816 / NM_206943.4; = p.S43R on NM_000627.4) | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100617921; called by muse, mutect2, varscan2
- LTBP1 | c.2264T>C p.V755A (on ENST00000404816 / NM_206943.4; = p.V429A on NM_000627.4) | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV100617922; called by muse, mutect2, varscan2
- LTBP1 | c.4355G>C p.C1452S (on ENST00000404816 / NM_206943.4; = p.C1126S on NM_000627.4) | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99698812; called by muse, mutect2, varscan2
- LTF | c.402C>A p.C134* | Nonsense Mutation (SNP) | VAF 26/31 reads (84%) | catalogued as COSV99211622; called by muse, mutect2, varscan2
- LY6D | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as COSV100009360; called by muse, mutect2, varscan2
- LZTR1 | c.1714G>T p.A572S | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.557); catalogued as rs768161325, COSV99302296; called by muse, mutect2, varscan2
- MAGEB2 | c.687G>T p.M229I | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.036); catalogued as rs1391671203, COSV100975752; called by muse, mutect2, varscan2
- MAGEC1 | c.3317C>A p.A1106D | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99596493; called by muse, mutect2, varscan2
- MAGI1 | c.4115G>A p.R1372Q | Missense Mutation (SNP) | VAF 60/82 reads (73%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV58327420; called by muse, mutect2, varscan2
- MAP1A | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.13); PolyPhen benign (0.22); catalogued as COSV100289218; called by muse, mutect2, varscan2
- MAP2K7 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs377648179; called by muse, mutect2, varscan2
- MARCHF7 | c.1580G>C p.R527T | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as rs781519217, COSV99374110; called by muse, mutect2, varscan2
- MARCHF9 | c.677T>A p.M226K | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99875035; called by muse, mutect2, varscan2
- MAST1 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.951); catalogued as COSV99263674; called by muse, mutect2, varscan2
- MBD2 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); catalogued as COSV99840441; called by muse, mutect2, varscan2
- MBD5 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs747127657, COSV68699289; called by muse, mutect2, varscan2
- MCF2L2 | c.1691C>A p.P564H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100192154; called by muse, mutect2, varscan2
- MCM8 | c.2428C>T p.Q810* | Nonsense Mutation (SNP) | VAF 21/34 reads (62%) | catalogued as COSV99496252; called by muse, mutect2, varscan2
- MDC1 | c.5738G>T p.G1913V | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100903079; called by muse, mutect2, varscan2
- MDM1 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.68); catalogued as COSV100292054; called by muse, mutect2, varscan2
- MEF2C | c.445G>T p.V149L | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV100426205; called by muse, mutect2
- MFN1 | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99764699; called by muse, mutect2, varscan2
- MFN1 | c.541G>T p.G181C | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99764700; called by muse, mutect2, varscan2
- MFN1 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs755879355, COSV99764702; called by muse, mutect2, varscan2
- MGAM | c.1903G>T p.D635Y | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101527744; called by muse, mutect2, varscan2
- MID2 | c.583T>A p.C195S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99465587; called by muse, mutect2, varscan2
- MINDY3 | c.1319G>T p.R440L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.072); catalogued as rs142355387, COSV99510989; called by muse, mutect2, varscan2
- MMP16 | c.1200C>A p.D400E | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV54149139, COSV54180953; called by muse, mutect2, varscan2
- MMP28 | c.1465G>T p.D489Y | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762709550; called by muse, mutect2, varscan2
- MMRN1 | c.2779G>C p.V927L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99307759; called by muse, mutect2, varscan2
- MN1 | c.3086A>T p.D1029V | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as COSV100180136; called by muse, mutect2
- MNDA | c.1093G>C p.D365H | Missense Mutation (SNP) | VAF 43/287 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63741540; called by muse, mutect2, varscan2
- MOB1A | c.169A>T p.I57F | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV101247359; called by muse, mutect2, varscan2
- MOB1A | c.168G>T p.W56C | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101247362; called by muse, mutect2, varscan2
- MOB3C | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.995); catalogued as COSV99596456; called by muse, mutect2, varscan2
- MPO | c.1969G>A p.V657M | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774394797, COSV51858210; called by muse, mutect2, varscan2
- MRC2 | c.1753C>A p.Q585K | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.416); catalogued as rs753963940, COSV100316762; called by muse, mutect2, varscan2
- MROH2B | c.3361T>A p.L1121I | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101270913; called by muse, mutect2, varscan2
- MRPL37 | c.345G>A p.E115= | Splice Region (SNP) | VAF 28/95 reads (29%) | catalogued as COSV99839191; called by muse, mutect2, varscan2
- MS4A7 | c.386G>C p.G129A | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.622); catalogued as COSV100279761; called by muse, varscan2
- MSR1 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100028117, COSV50512607; called by muse, mutect2, varscan2
- MTUS2 | c.1745A>T p.N582I | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV101462364; called by muse, mutect2, varscan2
- MUC16 | c.21144C>A p.D7048E | Missense Mutation (SNP) | VAF 68/92 reads (74%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.148); catalogued as COSV101201584; called by muse, mutect2, varscan2
- MUC16 | c.6569C>A p.S2190Y | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as COSV67491060, COSV67491381; called by muse, mutect2, varscan2
- MUC16 | c.4699G>T p.V1567L | Missense Mutation (SNP) | VAF 106/133 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); catalogued as COSV101201587; called by muse, mutect2, varscan2
- MUC17 | c.9506T>A p.M3169K | Missense Mutation (SNP) | VAF 260/323 reads (80%) | SIFT tolerated (1); PolyPhen benign (0.175); catalogued as COSV100075009; called by muse, mutect2, varscan2
- MUC17 | c.13077G>T p.Q4359H | Missense Mutation (SNP) | VAF 123/158 reads (78%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100075010; called by muse, mutect2, varscan2
- MVK | c.1175C>G p.A392G | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV99950115; called by muse, mutect2, varscan2
- MXRA5 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54254745, COSV99479172; called by muse, mutect2, varscan2
- MYH13 | c.1586C>A p.P529H | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52827603, COSV99355412; called by muse, mutect2
- MYH15 | c.368T>A p.L123Q | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99844286; called by muse, mutect2, varscan2
- MYH2 | c.5306C>A p.A1769D | Missense Mutation (SNP) | VAF 91/152 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99820945; called by muse, mutect2, varscan2
- MYH4 | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.244); catalogued as COSV55117129; called by muse, mutect2, varscan2
- MYH8 | c.3533G>C p.R1178P | Missense Mutation (SNP) | VAF 102/203 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101238775, COSV67972659; called by muse, mutect2, varscan2
- MYL4 | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100733180; called by muse, mutect2, varscan2
- MYO18B | c.6766G>T p.G2256W | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV100125129; called by muse, mutect2, varscan2
- MYOC | c.302A>T p.Q101L | Missense Mutation (SNP) | VAF 63/109 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV99231716; called by muse, mutect2, varscan2
- MYRIP | c.116T>A p.L39Q | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV100219988; called by muse, mutect2, varscan2
- MYT1 | c.1116G>C p.M372I | Missense Mutation (SNP) | VAF 61/76 reads (80%) | SIFT tolerated (0.79); PolyPhen benign (0.017); catalogued as COSV100115441; called by muse, mutect2, varscan2
- NAALADL2 | c.844G>T p.G282* | Nonsense Mutation (SNP) | VAF 25/36 reads (69%) | catalogued as COSV101380492; called by muse, mutect2, varscan2
- NAV2 | c.4202C>T p.P1401L (on ENST00000396087 / NM_001244963.2; = p.P1378L on NM_145117.5) | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100217629; called by muse, mutect2, varscan2
- NAV3 | c.2392C>A p.Q798K | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as COSV99895497; called by muse, mutect2, varscan2
- NBAS | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV99871552; called by muse, mutect2, varscan2
- NCAN | c.3034T>C p.C1012R | Missense Mutation (SNP) | VAF 81/107 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776895054, COSV99388308; called by muse, mutect2, varscan2
- NCK1 | c.893A>G p.E298G | Missense Mutation (SNP) | VAF 126/161 reads (78%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV99999833; called by muse, mutect2, varscan2
- NCKAP5L | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100259216; called by muse, mutect2, varscan2
- NELL1 | c.2387G>A p.G796E | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs771667370, COSV100125040; called by muse, mutect2, varscan2
- NHS | c.3641C>T p.T1214I | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.107); catalogued as COSV101196970; called by muse, mutect2, varscan2
- NID2 | c.2306T>A p.M769K | Missense Mutation (SNP) | VAF 46/55 reads (84%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV99357240; called by muse, mutect2, varscan2
- NIT2 | c.232A>T p.I78L | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV101237135; called by muse, mutect2, varscan2
- NKAPL | c.450A>C p.E150D | Missense Mutation (SNP) | VAF 111/243 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.681); catalogued as COSV100642581; called by muse, mutect2, varscan2
- NLGN1 | c.308C>A p.P103H | Missense Mutation (SNP) | VAF 126/284 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV100850171; called by muse, mutect2, varscan2
- NLGN1 | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100850172, COSV64324157, COSV64327004; called by muse, mutect2, varscan2
- NLGN4X | c.2138C>A p.P713H | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52014296, COSV99323854; called by muse, mutect2, varscan2
- NLRP13 | c.1743G>T p.W581C | Missense Mutation (SNP) | VAF 88/105 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100738516; called by muse, mutect2, varscan2
- NLRP2 | c.2108G>A p.G703D | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs777371558, COSV99672642; called by muse, mutect2, varscan2
- NLRP5 | c.1727G>T p.C576F | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.511); catalogued as COSV101173873; called by muse, mutect2, varscan2
- NNMT | c.290G>T p.W97L | Missense Mutation (SNP) | VAF 111/128 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100248933; called by muse, mutect2, varscan2
- NOC3L | c.898G>C p.G300R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100993396; called by muse, mutect2, varscan2
- NOL10 | c.1562T>C p.L521P | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); catalogued as COSV100630293; called by muse, mutect2
- NOL11 | c.43C>A p.L15M | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV99475289; called by muse, mutect2, varscan2
- NOTCH4 | c.1108T>A p.C370S | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100901013; called by muse, mutect2, varscan2
- NOVA1 | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99948711; called by muse, mutect2, varscan2
- NPAT | c.3644C>T p.S1215L | Missense Mutation (SNP) | VAF 341/381 reads (90%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV99586341; called by muse, varscan2
- NSMAF | c.2212-1G>T p.X738_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | catalogued as COSV99233451; called by muse, mutect2, varscan2
- NT5C1A | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148676406; called by muse, mutect2, varscan2
- NT5M | c.674A>G p.K225R | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101198661; called by muse, mutect2, varscan2
- NTN5 | c.838A>G p.I280V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.109); catalogued as COSV99539571; called by muse, mutect2, varscan2
- NTRK2 | c.274G>T p.G92* | Nonsense Mutation (SNP) | VAF 29/43 reads (67%) | catalogued as COSV99458494; called by muse, mutect2, varscan2
- NUDT12 | c.1089A>G p.I363M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.955); catalogued as COSV100048353; called by muse, mutect2, varscan2
- NUDT12 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100048355, COSV50091511; called by muse, mutect2, varscan2
- NUP205 | c.917A>G p.Y306C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs142367048; called by muse, mutect2, varscan2
- NUTM1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV100182438; called by muse, mutect2, varscan2
- NXPH2 | c.604C>A p.L202M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.951); catalogued as COSV99741306; called by muse, mutect2, varscan2
- NYAP2 | c.1581G>T p.K527N | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV99798446; called by muse, mutect2, varscan2
- OCIAD2 | c.66G>T p.Q22H | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as COSV99906686; called by muse, mutect2, varscan2
- OGFRL1 | c.582C>G p.F194L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.754); catalogued as COSV100965801, COSV64971706; called by muse, mutect2, varscan2
- OLR1 | c.754T>C p.Y252H | Missense Mutation (SNP) | VAF 111/137 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV100376438; called by muse, mutect2, varscan2
- OR10H4 | c.647T>A p.I216N | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs765854391, COSV100437778; called by muse, mutect2, varscan2
- OR10J1 | c.748C>G p.H250D | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101419800, COSV101420010; called by muse, mutect2, varscan2
- OR10J3 | c.420G>T p.R140S | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV100171859; called by muse, mutect2, varscan2
- OR11H1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 57/301 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.177); catalogued as COSV99422003; called by muse, mutect2, varscan2
- OR2A12 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.213); catalogued as COSV101283207; called by muse, mutect2, varscan2
- OR2A2 | c.793C>A p.Q265K | Missense Mutation (SNP) | VAF 123/254 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV101286673; called by muse, mutect2, varscan2
- OR2A25 | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 93/174 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV101376419; called by muse, mutect2, varscan2
- OR2D3 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV53491735, COSV53494354; called by muse, mutect2, varscan2
- OR2G6 | c.862A>T p.I288F | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV100598313; called by muse, mutect2, varscan2
- OR2L8 | c.878A>T p.N293I | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100594311, COSV61726121; called by muse, mutect2
- OR2W3 | c.919G>T p.G307W | Missense Mutation (SNP) | VAF 37/39 reads (95%) | SIFT tolerated (0.26); PolyPhen benign (0.315); catalogued as COSV64458208; called by muse, mutect2, varscan2
- OR4D5 | c.551T>A p.L184Q | Missense Mutation (SNP) | VAF 86/186 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100190182; called by muse, mutect2, varscan2
- OR4L1 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as COSV100235909; called by muse, mutect2, varscan2
- OR4N2 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 56/73 reads (77%) | catalogued as COSV60053195; called by muse, mutect2, varscan2
- OR4N5 | c.307T>C p.F103L | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100374236; called by muse, mutect2, varscan2
- OR51Q1 | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 117/148 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100333084; called by muse, mutect2, varscan2
- OR52A1 | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100200574, COSV100200583; called by muse, mutect2, varscan2
- OR52I1 | c.162G>C p.W54C | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100331819; called by mutect2, varscan2
- OR52I2 | c.240G>C p.W80C | Missense Mutation (SNP) | VAF 86/152 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100443015; called by muse, mutect2, varscan2
- OR5A2 | c.28G>T p.V10L | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV100119850; called by muse, mutect2, varscan2
- OR5B12 | c.338T>A p.L113Q | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1295083041, COSV100222560; called by muse, mutect2, varscan2
- OR5D18 | c.437T>C p.V146A | Missense Mutation (SNP) | VAF 140/179 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV100450890, COSV61737992; called by muse, mutect2, varscan2
- OR5D18 | c.810C>A p.H270Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV100450892, COSV61738130; called by muse, mutect2, varscan2
- OR5I1 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 44/50 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100041503, COSV100041697; called by muse, mutect2, varscan2
- OR5V1 | c.944T>C p.L315S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV101011467; called by muse, mutect2, varscan2
- OR6B3 | c.764T>G p.L255W | Missense Mutation (SNP) | VAF 73/85 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1181245173, COSV100097659; called by muse, mutect2, varscan2
- OR6N2 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 160/334 reads (48%) | catalogued as COSV100210479; called by muse, mutect2, varscan2
- OR6N2 | c.261T>G p.S87R | Missense Mutation (SNP) | VAF 159/337 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV100210481; called by muse, mutect2, varscan2
- OR7A17 | c.472T>A p.S158T | Missense Mutation (SNP) | VAF 81/106 reads (76%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV100541694; called by muse, mutect2, varscan2
- OR8A1 | c.523C>A p.H175N | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV99420840; called by muse, mutect2, varscan2
- OSBPL3 | c.2086G>T p.G696W | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100514525; called by muse, mutect2, varscan2
- P2RY10 | c.56G>C p.S19T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV99409391; called by muse, mutect2, varscan2
- PALLD | c.1736A>G p.K579R | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV99825789; called by muse, mutect2, varscan2
- PAN2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs372506474; called by muse, mutect2, varscan2
- PAQR8 | c.44G>T p.S15I | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100658527; called by muse, mutect2, varscan2
- PATJ | c.2222A>T p.N741I | Missense Mutation (SNP) | VAF 75/95 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100334955; called by muse, mutect2, varscan2
- PBXIP1 | c.1550G>C p.W517S | Missense Mutation (SNP) | VAF 79/465 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as COSV100870125; called by muse, mutect2, varscan2
- PCDH10 | c.534C>A p.N178K | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV99994475; called by muse, mutect2, varscan2
- PCDH8 | c.411G>T p.R137S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as COSV100132038; called by muse, mutect2, varscan2
- PCDH9 | c.6C>A p.D2E | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as COSV100123431; called by muse, mutect2, varscan2
- PCDHA2 | c.1504C>A p.R502S | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.649); catalogued as rs551711072, COSV100974137; called by muse, mutect2, varscan2
- PCDHA2 | c.2059G>T p.A687S | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.015); catalogued as COSV100974138, COSV65371086; called by muse, mutect2, varscan2
- PCDHA6 | c.1449C>G p.D483E | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100971799, COSV65344704, COSV65346009; called by muse, mutect2, varscan2
- PCDHA6 | c.2114G>T p.C705F | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100971801; called by muse, mutect2, varscan2
- PCDHA9 | c.1873G>T p.G625W | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV100970081; called by muse, mutect2, varscan2
- PCDHB1 | c.1795C>A p.Q599K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV100128405; called by muse, mutect2, varscan2
- PCDHB16 | c.208G>C p.G70R | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV99502851; called by muse, mutect2, varscan2
- PCDHB5 | c.110A>T p.E37V | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV99169512; called by muse, mutect2, varscan2
- PCDHGA11 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs865974752, COSV99546632; called by muse, mutect2, varscan2
- PCDHGA3 | c.1927G>C p.V643L | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.079); catalogued as COSV53962802, COSV54035651, COSV99546627; called by muse, mutect2, varscan2
- PCSK1 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 95/259 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100227268; called by muse, mutect2, varscan2
- PCSK6 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100084061; called by muse, mutect2, varscan2
- PCYT1A | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV99492445; called by muse, mutect2, varscan2
- PDCD11 | c.2957G>T p.G986V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV100874416; called by muse, mutect2, varscan2
- PDE10A | c.2299C>T p.R767* | Nonsense Mutation (SNP) | VAF 30/123 reads (24%) | catalogued as rs141939882, COSV63096689, COSV63099141; called by muse, mutect2, varscan2
- PDE4B | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 148/206 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV100304948; called by muse, mutect2, varscan2
- PDZD8 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57825657; called by muse, mutect2, varscan2
- PES1 | c.1531G>T p.V511L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV100073335, COSV58828892; called by muse, mutect2, varscan2
- PHF3 | c.776C>G p.S259* | Nonsense Mutation (SNP) | VAF 25/133 reads (19%) | catalogued as COSV100013966, COSV50315166; called by muse, mutect2, varscan2
- PHOSPHO2 | c.550G>T p.V184F | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99775763, COSV99776120; called by muse, mutect2, varscan2
- PIF1 | c.724C>G p.L242V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.045); catalogued as COSV51424757, COSV99165241; called by muse, mutect2, varscan2
- PIGQ | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 81/307 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs146507621; called by muse, mutect2, varscan2
- PIK3R4 | c.3724G>T p.V1242F | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100650921, COSV62038128; called by muse, mutect2, varscan2
- PIP | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 149/556 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.393); catalogued as COSV99344092, COSV99344258; called by muse, mutect2, varscan2
- PIP4K2A | c.1140C>T p.G380= | Splice Region (SNP) | VAF 111/229 reads (48%) | catalogued as rs549534439, COSV60541739; called by muse, mutect2, varscan2
- PKD1L1 | c.5852A>G p.Y1951C | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV99221319; called by muse, mutect2, varscan2
- PKHD1 | c.1985A>T p.D662V | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV100584528; called by muse, mutect2, varscan2
- PKHD1L1 | c.4388C>A p.T1463K | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1382518643, COSV101006808; called by muse, mutect2, varscan2
- PLEKHA3 | c.41-1G>T p.X14_splice | Splice Site (SNP) | VAF 26/98 reads (27%) | catalogued as COSV99317890; called by muse, varscan2
- PLEKHA3 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99317892; called by muse, varscan2
- PLEKHM3 | c.1561A>T p.I521L | Missense Mutation (SNP) | VAF 73/105 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV101216864; called by muse, mutect2, varscan2
- PLSCR4 | c.175G>T p.G59* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100724350; called by muse, mutect2, varscan2
- PMFBP1 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.23); catalogued as COSV99401512; called by muse, mutect2, varscan2
- PNLIPRP1 | c.465G>A p.L155= | Splice Region (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100724522; called by muse, mutect2, varscan2
- PNO1 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99721605; called by muse, mutect2, varscan2
- POLQ | c.4592A>T p.D1531V | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT tolerated (0.3); PolyPhen benign (0.08); catalogued as COSV99952942; called by muse, mutect2, varscan2
- POLR1A | c.1562A>T p.Q521L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV99808399; called by muse, mutect2, varscan2
- POLR1E | c.1067G>A p.R356Q (on ENST00000377792 / NM_001282766.1; = p.R294Q on NM_022490.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV66771523; called by muse, mutect2, varscan2
- POLR1F | c.254+1G>T p.X85_splice | Splice Site (SNP) | VAF 58/140 reads (41%) | catalogued as COSV99749069; called by muse, mutect2, varscan2
- POP7 | c.199T>A p.S67T | Missense Mutation (SNP) | VAF 87/225 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100292193; called by muse, mutect2, varscan2
- POT1 | c.1806G>T p.W602C | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100714144; called by muse, mutect2, varscan2
- POTEH | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100625189; called by muse, varscan2
- POTEM | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.022); catalogued as rs552718195; called by mutect2, varscan2
- POU3F1 | c.1122C>A p.D374E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV100884723; called by muse, mutect2, varscan2
- POU3F4 | c.330C>A p.H110Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100937327; called by muse, mutect2, varscan2
- PPARGC1A | c.2290C>G p.L764V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99338641; called by muse, mutect2, varscan2
- PPM1H | c.704T>A p.I235N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99956531; called by muse, mutect2, varscan2
- PPP1R12B | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100408447; called by muse, mutect2, varscan2
- PPP1R3A | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 56/85 reads (66%) | catalogued as COSV99494253; called by muse, mutect2, varscan2
- PPP3CA | c.1157-1G>T p.X386_splice | Splice Site (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100548034; called by muse, mutect2, varscan2
- PPP3R2 | c.478C>A p.L160M | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV100701822; called by muse, mutect2, varscan2
- PRDM14 | c.1029G>T p.Q343H | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52572110, COSV52574705; called by muse, mutect2, varscan2
- PRDM9 | c.383C>A p.S128Y | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.133); catalogued as COSV57009120, COSV99691235; called by muse, mutect2, varscan2
- PRDM9 | c.610+1G>T p.X204_splice | Splice Site (SNP) | VAF 37/159 reads (23%) | catalogued as COSV99691239; called by muse, mutect2, varscan2
- PRDX3 | c.243G>T p.E81D | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100045447; called by muse, mutect2, varscan2
- PRG4 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0.159); catalogued as COSV100825945; called by muse, varscan2
- PRKD1 | c.2618C>A p.A873E | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV100121493, COSV59585065; called by muse, mutect2, varscan2
- PRKDC | c.1697A>G p.D566G | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs1220400721, COSV100042789; called by muse, mutect2, varscan2
- PRMT8 | c.1138G>T p.G380* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99713685; called by muse, mutect2, varscan2
- PRODH2 | c.1149T>A p.Y383* (on ENST00000301175; = p.Y307* on NM_021232.2 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 95/127 reads (75%) | catalogued as COSV99995520; called by muse, mutect2, varscan2
- PRR27 | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 48/60 reads (80%) | SIFT tolerated (0.62); PolyPhen benign (0.028); catalogued as COSV100748903; called by muse, mutect2, varscan2
- PRRG3 | c.250G>T p.V84L | Missense Mutation (SNP) | VAF 89/132 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV100948696; called by muse, mutect2, varscan2
- PRSS22 | c.540G>T p.W180C | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99361987; called by muse, mutect2, varscan2
- PRUNE2 | c.4856C>T p.P1619L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV100945114; called by muse, mutect2, varscan2
- PSG6 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 205/256 reads (80%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.792); catalogued as rs898713012, COSV99414536; called by muse, mutect2, varscan2
- PSMD8 | c.1013A>T p.Q338L | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0.05); PolyPhen benign (0.23); catalogued as COSV99287680; called by muse, mutect2, varscan2
- PSPC1 | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 25/175 reads (14%) | catalogued as COSV58888835; called by muse, mutect2, varscan2
- PTCHD4 | c.1166G>A p.C389Y | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV100261616, COSV100261719; called by muse, mutect2, varscan2
- PTGS2 | c.1702G>T p.V568F | Missense Mutation (SNP) | VAF 71/99 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100821846; called by muse, mutect2, varscan2
- PTGS2 | c.1304A>T p.Q435L | Missense Mutation (SNP) | VAF 49/66 reads (74%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV66568243; called by muse, mutect2, varscan2
- PTK7 | c.1969G>T p.E657* | Nonsense Mutation (SNP) | VAF 235/325 reads (72%) | catalogued as COSV100030617, COSV57847436; called by muse, mutect2, varscan2
- PTPN14 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.237); catalogued as COSV65284753; called by muse, mutect2, varscan2
- PTPRD | c.3115G>C p.E1039Q | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100646890, COSV61958633; called by muse, mutect2, varscan2
- PTPRH | c.1939G>T p.A647S | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); catalogued as COSV99671442; called by muse, mutect2, varscan2
- PTPRN2 | c.1342A>G p.K448E | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as COSV101235331; called by muse, mutect2, varscan2
- PTPRZ1 | c.791G>C p.C264S | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101100832; called by muse, mutect2, varscan2
- PXDNL | c.1687G>T p.G563C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100686267; called by muse, mutect2, varscan2
- PXDNL | c.316T>C p.Y106H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); catalogued as COSV100686269; called by muse, mutect2, varscan2
- PXYLP1 | c.959A>T p.H320L | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV99649807; called by muse, mutect2, varscan2
- RAB6C | c.122C>A p.T41N | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.044); catalogued as COSV101308562; called by muse, mutect2, varscan2
- RAD17 | c.268C>T p.P90S (on ENST00000380774 / NM_133339.2; = p.P79S on NM_002873.1) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as COSV99281759; called by muse, mutect2, varscan2
- RANBP2 | c.86G>C p.G29A | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99313226; called by muse, mutect2, varscan2
- RAP1GDS1 | c.518A>C p.Q173P (on ENST00000408927 / NM_001100427.2; = p.Q174P on NM_021159.5) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99217406; called by muse, mutect2, varscan2
- RASEF | c.938A>G p.D313G | Missense Mutation (SNP) | VAF 35/40 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV100907052; called by muse, mutect2, varscan2
- RASGRF2 | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99430316; called by muse, mutect2, varscan2
- RBM12B | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.237); catalogued as COSV101197163; called by muse, mutect2, varscan2
- RBM33 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100265729; called by muse, mutect2, varscan2
- RBM4 | c.901A>T p.T301S | Missense Mutation (SNP) | VAF 79/99 reads (80%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100029733; called by muse, mutect2, varscan2
- RBMXL2 | c.672C>A p.D224E | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as COSV100182550; called by muse, mutect2, varscan2
- REG3A | c.196-1G>T p.X66_splice | Splice Site (SNP) | VAF 13/89 reads (15%) | catalogued as COSV100532547, COSV100532917; called by muse, mutect2, varscan2
- RELCH | c.1901A>G p.E634G | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99902793; called by muse, mutect2, varscan2
- RET | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as COSV100394535; called by muse, mutect2, varscan2
- RFPL3 | c.816C>G p.S272R (on ENST00000249007 / NM_001098535.1; = p.S243R on NM_006604.2) | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs759102145, COSV99966973, COSV99967279; called by muse, mutect2, varscan2
- RGS9 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); catalogued as rs759032207, COSV99287107; called by muse, mutect2, varscan2
- RHOXF2 | c.423C>A p.F141L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV101002785; called by muse, mutect2, varscan2
- RIMS2 | c.3677G>T p.G1226V | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (1); catalogued as COSV51693305; called by muse, mutect2, varscan2
- RNF113B | c.64T>A p.F22I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV99940420; called by muse, mutect2, varscan2
- RNF213 | c.11107G>A p.E3703K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.036); catalogued as rs771794678, COSV100301471; called by muse, mutect2, varscan2
- RPA4 | c.676C>G p.Q226E | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100235274; called by muse, mutect2, varscan2
- RPL5 | c.584A>T p.H195L | Missense Mutation (SNP) | VAF 35/40 reads (88%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV100240495; called by muse, mutect2, varscan2
- RPTOR | c.654G>A p.E218= | Splice Region (SNP) | VAF 10/112 reads (9%) | catalogued as COSV100157233; called by muse, mutect2, varscan2
- RREB1 | c.1567A>T p.T523S | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100619840; called by muse, mutect2, varscan2
- RTN1 | c.694A>G p.K232E | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99956824; called by muse, mutect2, varscan2
- RTN4RL1 | c.291G>T p.E97D | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.103); catalogued as COSV100486811; called by muse, mutect2, varscan2
- RTTN | c.2537T>A p.V846D | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.232); catalogued as COSV99733791; called by muse, mutect2, varscan2
- RXFP2 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs373570227; called by muse, mutect2, varscan2
- RYR2 | c.4784T>G p.L1595R | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.648); catalogued as COSV100772849; called by muse, mutect2, varscan2
- RYR3 | c.4168G>T p.V1390F | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs138445751, COSV101214499; called by muse, mutect2, varscan2
- RYR3 | c.4868T>C p.L1623P | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); catalogued as COSV101214501; called by muse, mutect2, varscan2
- SAMD7 | c.737C>T p.T246I | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100157075; called by muse, mutect2, varscan2
- SCN1A | c.3649C>A p.H1217N (on ENST00000303395 / NM_001202435.3; = p.H1206N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100322063; called by muse, mutect2, varscan2
- SCN1A | c.1802A>G p.N601S | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.137); catalogued as COSV100320059, COSV100322073; called by muse, mutect2, varscan2
- SCN1A | c.1223T>A p.F408Y | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100322082; called by muse, mutect2
- SCN4A | c.4267G>T p.V1423F | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101438650; called by muse, mutect2, varscan2
- SCN4A | c.1900C>G p.P634A | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV101438651; called by muse, mutect2, varscan2
- SCN5A | c.2697G>T p.W899C | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100350526; called by muse, mutect2, varscan2
- SCP2D1 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.674); catalogued as COSV99602208; called by muse, mutect2
- SELENBP1 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 93/292 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100923689; called by muse, mutect2, varscan2
- SEMA6D | c.1251C>A p.V417= | Splice Region (SNP) | VAF 44/48 reads (92%) | catalogued as COSV100317599; called by muse, mutect2, varscan2
- SENP7 | c.2823G>T p.L941F | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100053868; called by muse, mutect2, varscan2
- SERPINA5 | c.609C>G p.I203M | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100291819; called by muse, mutect2, varscan2
- SERPINB11 | c.38T>A p.L13H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV101236335; called by muse, mutect2, varscan2
- SERPINB4 | c.511G>C p.D171H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100346002, COSV61984831, COSV61985480; called by muse, mutect2, varscan2
- SEZ6 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100253541; called by muse, mutect2, varscan2
- SH2B2 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100159605; called by muse, mutect2, varscan2
- SH3RF1 | c.2111C>T p.S704L | Missense Mutation (SNP) | VAF 72/96 reads (75%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99499498; called by muse, mutect2, varscan2
- SHISA2 | c.718G>T p.G240W | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100096191, COSV100096365; called by muse, mutect2, varscan2
- SHOX2 | c.632C>A p.A211D (on ENST00000441443 / NM_006884.3; = p.A235D on NM_003030.4) | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV101273835; called by muse, mutect2, varscan2
- SI | c.1445G>T p.C482F | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs755058324, COSV100017134; called by muse, mutect2, varscan2
- SIPA1L2 | c.4815A>T p.L1605= | Splice Region (SNP) | VAF 61/74 reads (82%) | catalogued as COSV99479657; called by muse, mutect2, varscan2
- SIRT7 | c.876G>C p.K292N | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV100155740, COSV58712366; called by muse, mutect2, varscan2
- SIX1 | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV99903485; called by muse, mutect2, varscan2
- SIX3 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV99578563; called by muse, mutect2, varscan2
- SLAMF8 | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 171/561 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99223099; called by muse, mutect2, varscan2
- SLC10A2 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (0.14); PolyPhen benign (0.123); catalogued as COSV99808262; called by muse, mutect2, varscan2
- SLC16A7 | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99676864; called by muse, mutect2, varscan2
- SLC17A4 | c.1029C>G p.I343M | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV100930546; called by muse, mutect2, varscan2
- SLC18A3 | c.1106C>A p.A369D | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.723); catalogued as COSV100340864; called by muse, mutect2, varscan2
- SLC1A1 | c.1508A>C p.Y503S | Missense Mutation (SNP) | VAF 61/70 reads (87%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.546); catalogued as COSV99261585; called by muse, mutect2, varscan2
- SLC22A11 | c.1166G>T p.R389L | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV100102666; called by muse, mutect2, varscan2
- SLC22A12 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs376338940; called by muse, mutect2, varscan2
- SLC22A23 | c.1414A>T p.T472S | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.022); catalogued as COSV100978388; called by muse, mutect2, varscan2
- SLC22A8 | c.763T>G p.W255G | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100268090; called by muse, mutect2, varscan2
- SLC27A3 | c.2260-2A>C p.X754_splice (on ENST00000271857; = p.X626_splice on NM_024330.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 68/140 reads (49%) | catalogued as COSV99670170; called by muse, mutect2, varscan2
- SLC35C2 | c.748G>T p.G250W | Missense Mutation (SNP) | VAF 59/78 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54758258, COSV99709569; called by muse, mutect2, varscan2
- SLC35F6 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs746493220, COSV100733740; called by muse, mutect2, varscan2
- SLC38A11 | c.331C>T p.P111S (on ENST00000409149 / NM_001351539.1; = p.P89S on NM_173512.2) | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58052857; called by muse, mutect2, varscan2
- SLC39A12 | c.1033C>G p.L345V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101070156; called by muse, mutect2, varscan2
- SLC39A12 | c.1291G>T p.E431* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | catalogued as COSV101070159, COSV66199180; called by muse, varscan2
- SLC44A4 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1429376747, COSV99999283; called by muse, mutect2, varscan2
- SLC7A3 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.119); catalogued as COSV99979845; called by muse, mutect2, varscan2
- SLC8A1 | c.2204T>A p.L735Q | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100247392; called by muse, mutect2, varscan2
- SLC9B1 | c.1434G>T p.L478F | Missense Mutation (SNP) | VAF 38/426 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56469846, COSV56470599; called by muse, mutect2
- SLCO4A1 | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 56/78 reads (72%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); catalogued as rs145692715, COSV99415108; called by muse, mutect2, varscan2
- SLIT1 | c.1676G>T p.G559V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56588562, COSV99822607; called by muse, mutect2, varscan2
- SLIT1 | c.1675G>T p.G559W | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99822472; called by muse, mutect2, varscan2
- SLITRK1 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1382961507, COSV101000060; called by muse, mutect2, varscan2
- SLITRK1 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.758); catalogued as COSV101000062; called by muse, mutect2, varscan2
- SLX4IP | c.1175C>T p.T392I | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100570843; called by muse, mutect2, varscan2
- SMC3 | c.400A>T p.N134Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100700049; called by muse, mutect2, varscan2
- SMYD3 | c.1066G>A p.E356K (on ENST00000490107 / NM_001375962.1; = p.E297K on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.162); catalogued as rs760848607, COSV100830950; called by muse, mutect2, varscan2
- SNRPN | c.359T>C p.I120T | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV100578619; called by muse, mutect2, varscan2
- SNX1 | c.386C>A p.P129Q | Missense Mutation (SNP) | VAF 66/86 reads (77%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as rs200079069, COSV99976407; called by muse, mutect2, varscan2
- SOBP | c.2558G>T p.G853V | Missense Mutation (SNP) | VAF 64/83 reads (77%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100433411, COSV58001605; called by muse, mutect2, varscan2
- SORBS2 | c.709G>A p.D237N (on ENST00000284776 / NM_021069.5; = p.D330N on NM_003603.6) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as rs760604818, COSV53018408, COSV99512725; called by muse, mutect2, varscan2
- SORCS1 | c.1963C>A p.R655S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53845885, COSV99550213; called by muse, mutect2, varscan2
- SORCS1 | c.1536G>T p.R512S | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV99550217; called by muse, mutect2, varscan2
- SORCS3 | c.2548-1G>T p.X850_splice | Splice Site (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99056369; called by muse, mutect2, varscan2
501 further variants in this file (191 protein-altering or splice-affecting, 279 silent, 31 other) are not listed here.
